Somatic mutation profile of tumor specimen TCGA-51-6867-01A (aliquot TCGA-51-6867-01A-11D-2042-08) from TCGA case TCGA-51-6867, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 72.6 years (26,523 days).
Specimen TCGA-51-6867-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c8c58ae-57f3-4acb-9282-4a6607a13a7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-51-6867-11A (Solid Tissue Normal), aliquot TCGA-51-6867-11A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98dc4c3e-8f1f-425c-9477-a42b0351d19f

The open-access MAF lists 662 somatic variants for this specimen: 515 protein-altering or splice-affecting, 131 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 453, Silent 131, Nonsense Mutation 28, Splice Site 17, Frame Shift Del 11, Intron 5, In Frame Del 3, RNA 3, 5'UTR 3, 5'Flank 2, Splice Region 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LEMD3 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as rs749951964, CM061095, COSV57653886; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 22/28 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2062C>G p.L688V | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99714141; called by muse, mutect2, varscan2
- ABCB10 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV60622067; called by muse, mutect2, varscan2
- ABCC2 | c.4063G>C p.G1355R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); catalogued as COSV100966682; called by muse, mutect2, varscan2
- ABCC8 | c.1532T>A p.L511Q | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100217652; called by muse, varscan2
- ABLIM1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99522654; called by muse, mutect2, varscan2
- ACKR1 | c.651C>G p.I217M | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100929647; called by muse, mutect2, varscan2
- ADAM22 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.149); catalogued as COSV99718073; called by muse, mutect2, varscan2
- ADAMTS12 | c.4378del p.R1460Dfs*93 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | catalogued as COSV61262356; called by mutect2, pindel, varscan2
- ADAMTS18 | c.567C>A p.H189Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.356); catalogued as rs759363189, COSV99273938; called by muse, mutect2
- ADCY1 | c.3254G>T p.R1085I | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV99812788; called by muse, mutect2, varscan2
- ADGRL4 | c.1903G>T p.V635F | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs762938384, COSV100876494; called by muse, mutect2, varscan2
- ADGRV1 | c.2662G>T p.G888C | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101316398; called by muse, mutect2, varscan2
- ADGRV1 | c.2663G>T p.G888V | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315541, COSV101316400; called by muse, mutect2, varscan2
- ADGRV1 | c.16997C>A p.A5666D | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV101316402; called by muse, mutect2, varscan2
- AGO1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as rs759454083, COSV100940915; called by muse, mutect2, varscan2
- AKNAD1 | c.485A>T p.K162I | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV100645811; called by muse, mutect2, varscan2
- AKT1 | c.854A>T p.D285V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100838291; called by muse, mutect2, varscan2
- AL031777.2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious, low confidence (0.04); catalogued as COSV100587264, COSV61912013, COSV61912148; called by muse, mutect2, varscan2
- ANKIB1 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99729837; called by muse, mutect2, varscan2
- ANKRD33 | c.556G>C p.A186P (on ENST00000340970 / NM_001304459.2; = p.A311P on NM_182608.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100001493; called by muse, mutect2, varscan2
- ANKRD49 | c.216A>C p.K72N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100120004; called by muse, mutect2, varscan2
- ANP32E | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV100029753, COSV58481613; called by muse, mutect2, varscan2
- ANPEP | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV100263330, COSV100263454; called by muse, mutect2, varscan2
- APBA1 | c.1160C>A p.P387H | Missense Mutation (SNP) | VAF 71/104 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99596991; called by muse, mutect2, varscan2
- APLNR | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV57243140, COSV57244060; called by muse, mutect2
- APLNR | c.518T>A p.L173* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV99951632; called by muse, mutect2
- AQP4 | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV101270559, COSV67218294; called by muse, mutect2, varscan2
- ARF1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 27/126 reads (21%) | catalogued as COSV99683326; called by muse, mutect2, varscan2
- ARHGAP28 | c.1892C>T p.S631L (on ENST00000383472 / NM_001366230.1; = p.S472L on NM_001010000.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.313); catalogued as rs142301237; called by muse, mutect2, varscan2
- ARHGAP31 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | catalogued as COSV99957644; called by muse, mutect2, varscan2
- ARHGAP9 | c.372G>T p.R124S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.027); catalogued as COSV100712511; called by muse, mutect2, varscan2
- ARHGDIA | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.248); catalogued as rs775688385, COSV99482633; called by muse, mutect2, varscan2
- ARID1A | c.1803+1G>C p.X601_splice | Splice Site (SNP) | VAF 78/112 reads (70%) | catalogued as COSV100253140; called by muse, mutect2, varscan2
- ARID1B | c.4562G>T p.R1521L | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as COSV51664893, COSV99271529; called by muse, mutect2, varscan2
- ARPC3 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV99959589; called by muse, mutect2, varscan2
- ASH1L | c.8252C>T p.P2751L (on ENST00000368346 / NM_001366177.2; = p.P2746L on NM_018489.3) | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100853577; called by muse, mutect2, varscan2
- ASIC2 | c.563C>A p.T188K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56766489; called by muse, mutect2, varscan2
- ASMT | c.333G>C p.R111S | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.372); catalogued as COSV101172520; called by muse, mutect2, varscan2
- ASPM | c.1867C>A p.P623T | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs145625555; called by muse, mutect2, varscan2
- ASPM | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 132/235 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54140119; called by muse, mutect2, varscan2
- ATAT1 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99457900; called by muse, mutect2, varscan2
- ATOH1 | c.1015G>C p.G339R | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100024566; called by muse, mutect2, varscan2
- ATP10B | c.2187C>A p.H729Q | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs761911543, COSV100515649, COSV59168554; called by muse, mutect2, varscan2
- ATP13A3 | c.3190G>A p.D1064N | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1408515540, COSV99757571; called by muse, mutect2
- ATP6V0A4 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 140/296 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100023603; called by muse, varscan2
- ATP8A2 | c.2387T>C p.V796A | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs893921466, COSV99683891; called by muse, mutect2, varscan2
- B3GAT2 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 79/129 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV57642995; called by muse, mutect2, varscan2
- BBS2 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV99802753; called by muse, mutect2, varscan2
- BICRA | c.40T>C p.C14R | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101194457; called by muse, mutect2, varscan2
- BMP1 | c.904A>G p.R302G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100110064; called by muse, mutect2, varscan2
- BMPR2 | c.305C>G p.T102S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.674); catalogued as COSV101001626; called by muse, mutect2, varscan2
- BNC2 | c.2767G>T p.A923S | Missense Mutation (SNP) | VAF 64/91 reads (70%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as rs145962490, COSV101036861; called by muse, mutect2, varscan2
- BST2 | c.435C>A p.S145R | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV53089857, COSV53089946; called by muse, mutect2, varscan2
- BTK | c.1921C>A p.R641S | Missense Mutation (SNP) | VAF 79/108 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM092954, CM950178, COSV100437867; called by muse, mutect2, varscan2
- BTLA | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as COSV100569823; called by muse, mutect2, varscan2
- C8orf33 | c.131G>T p.C44F | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as COSV100510609; called by muse, mutect2, varscan2
- C9orf131 | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV100398260; called by muse, mutect2, varscan2
- C9orf135 | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV99058613; called by muse, mutect2, varscan2
- CACNA1E | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100704850, COSV62397109; called by muse, varscan2
- CACNA1E | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100704853; called by muse, varscan2
- CACNA1E | c.2899G>T p.G967C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100704854; called by muse, mutect2
- CACNA1S | c.1533C>G p.I511M | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV100754821, COSV99054157; called by muse, mutect2
- CACNA2D4 | c.2465G>T p.G822V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99766389; called by muse, mutect2, varscan2
- CALN1 | c.484G>A p.E162K (on ENST00000329008 / NM_001017440.3; = p.E204K on NM_031468.4) | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as rs986071612, COSV100208940; called by muse, mutect2, varscan2
- CAP2 | c.1129A>T p.N377Y | Missense Mutation (SNP) | VAF 112/212 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012822; called by muse, mutect2, varscan2
- CAPSL | c.33G>T p.M11I | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV101274327; called by muse, mutect2, varscan2
- CCND1 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV57121314; called by muse, mutect2, varscan2
- CCT3 | c.1600A>G p.S534G | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99827482; called by muse, mutect2, varscan2
- CCT3 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99827483; called by muse, mutect2, varscan2
- CCT5 | c.1142G>C p.R381T | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV99725571; called by muse, mutect2, varscan2
- CD1E | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100937055; called by muse, mutect2, varscan2
- CD84 | c.264A>T p.L88F | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100246246; called by muse, mutect2, varscan2
- CDC27 | c.1150A>G p.S384G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.182); catalogued as rs1335540263, COSV99296227; called by muse, mutect2, varscan2
- CDH13 | c.1157A>T p.E386V | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.575); catalogued as COSV99230154; called by muse, mutect2, varscan2
- CDH15 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57024530, COSV99228789; called by muse, mutect2
- CDH18 | c.1327A>G p.T443A | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1409678142, COSV99937796; called by muse, mutect2, varscan2
- CDHR3 | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100488808, COSV58413788; called by muse, mutect2, varscan2
- CDK13 | c.2998G>T p.D1000Y | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99476009; called by muse, mutect2, varscan2
- CDS1 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV99881054, COSV99881217; called by muse, mutect2, varscan2
- CEP162 | c.2991G>A p.M997I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1197227821, COSV57623462; called by muse, mutect2, varscan2
- CEP70 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as rs1351560377, COSV99389501; called by muse, mutect2
- CEP85L | c.1549G>C p.D517H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100874350; called by muse, mutect2, varscan2
- CFAP54 | c.5436G>T p.R1812S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV100733242; called by muse, mutect2, varscan2
- CFAP54 | c.7610C>G p.A2537G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100733301; called by muse, mutect2, varscan2
- CGB1 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV100031748; called by muse, mutect2, varscan2
- CHRNA7 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100181666; called by mutect2, varscan2
- CHRNB2 | c.539G>C p.R180P | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV100872666, COSV63808975; called by muse, mutect2, varscan2
- CHRND | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286115; called by muse, mutect2
- CHRND | c.1064T>C p.L355P | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99286118; called by muse, mutect2
- CNTLN | c.1856A>G p.K619R | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs895705001, COSV99265430; called by muse, mutect2, varscan2
- CNTNAP2 | c.3206C>A p.S1069Y | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100670973; called by muse, mutect2, varscan2
- COL14A1 | c.2743G>T p.V915L | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV52864398, COSV99920451; called by muse, mutect2, varscan2
- COL3A1 | c.3409G>T p.G1137C | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100483644; called by muse, mutect2, varscan2
- COL5A3 | c.3553T>C p.S1185P | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99318404; called by muse, mutect2, varscan2
- COL6A3 | c.6398C>T p.P2133L | Missense Mutation (SNP) | VAF 202/314 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99800860; called by muse, varscan2
- COL6A3 | c.6397C>A p.P2133T | Missense Mutation (SNP) | VAF 200/311 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV99800862; called by muse, varscan2
- COL6A3 | c.4286-1G>A p.X1429_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99799866; called by muse, mutect2, varscan2
- COL9A3 | c.467C>G p.P156R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100673563; called by muse, mutect2, varscan2
- COMMD10 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99174581; called by muse, mutect2
- CRB1 | c.2146T>C p.F716L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100958058, COSV66330407; called by muse, mutect2, varscan2
- CRIM1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as COSV99752785, COSV99754301; called by muse, mutect2
- CSMD1 | c.10264G>T p.A3422S (on ENST00000520002; = p.A3421S on NM_033225.6) | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1490467009, COSV100153012; called by muse, mutect2, varscan2
- CSMD1 | c.6884G>T p.G2295V (on ENST00000520002; = p.G2294V on NM_033225.6) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153018; called by muse, varscan2
- CSMD3 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as COSV99822283; called by muse, mutect2, varscan2
- CTSC | c.1286G>A p.W429* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as rs887942959, CM993139, COSV99910931; called by muse, mutect2, varscan2
- DBNL | c.836-1G>T p.X279_splice (on ENST00000448521 / NM_001014436.3; = p.X280_splice on NM_014063.7) | Splice Site (SNP) | VAF 16/29 reads (55%) | catalogued as COSV99803868; called by muse, mutect2, varscan2
- DDX42 | c.1901A>T p.Q634L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV63790450; called by muse, mutect2, varscan2
- DEGS1 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 86/168 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100083455; called by muse, mutect2, varscan2
- DENND2A | c.1959+1G>A p.X653_splice | Splice Site (SNP) | VAF 20/43 reads (47%) | catalogued as COSV99326888; called by muse, mutect2, varscan2
- DENND2A | c.775A>T p.T259S | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99326891; called by muse, varscan2
- DENND4C | c.2121-1G>T p.X707_splice | Splice Site (SNP) | VAF 10/16 reads (63%) | catalogued as rs1430764351; called by muse, mutect2
- DGKD | c.694-1G>C p.X232_splice (on ENST00000264057 / NM_152879.3; = p.X188_splice on NM_003648.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99897438; called by muse, mutect2, varscan2
- DHRS9 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100513663; called by muse, mutect2, varscan2
- DHX34 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV100169860; called by muse, mutect2, varscan2
- DLGAP2 | c.900C>A p.D300E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs200420347, COSV70096649, COSV70102718; called by muse, mutect2, varscan2
- DNAH10 | c.5124G>T p.E1708D (on ENST00000409039; = p.E1647D on NM_207437.3) | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101292574; called by muse, mutect2, varscan2
- DNTT | c.846C>A p.S282R | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.428); catalogued as COSV100960732; called by muse, mutect2, varscan2
- DNTT | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV100960733; called by muse, mutect2, varscan2
- DOCK2 | c.1869G>T p.W623C | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99914887; called by muse, mutect2, varscan2
- DPPA2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs747129141, COSV101524768, COSV72118254; called by muse, mutect2
- DTX3L | c.1403C>G p.T468S | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.313); catalogued as rs1438598982, COSV99950141; called by muse, mutect2, varscan2
- EBF3 | c.38C>A p.T13K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.116); catalogued as rs1175268802, COSV100799572, COSV62482301; called by muse, mutect2, varscan2
- ECM2 | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.395); catalogued as COSV100755960; called by muse, mutect2, varscan2
- EGLN1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100791319; called by muse, mutect2, varscan2
- EML5 | c.2765A>T p.D922V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100716117; called by muse, mutect2, varscan2
- EML5 | c.2567A>T p.Y856F | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV100716122; called by muse, mutect2, varscan2
- EPHA6 | c.2904G>C p.E968D | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67587218, COSV67591992; called by muse, mutect2
- EPHB1 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 101/685 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV67655842, COSV67670717; called by muse, mutect2, varscan2
- ESRRG | c.756G>C p.M252I | Missense Mutation (SNP) | VAF 53/72 reads (74%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.456); catalogued as COSV100753773, COSV63163591; called by muse, mutect2, varscan2
- EXT1 | c.818C>G p.T273R | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT tolerated (0.36); PolyPhen benign (0.221); catalogued as rs1185024233, COSV100984124; called by muse, mutect2, varscan2
- F11 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99251798; called by muse, mutect2, varscan2
- FAM135B | c.1657T>A p.Y553N | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV99420863, COSV99426913; called by muse, mutect2, varscan2
- FAM234A | c.1344G>T p.T448= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as COSV51452686, COSV99395988; called by muse, mutect2, varscan2
- FAM47A | c.1727G>C p.R576P | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as COSV60495676, COSV60499390; called by muse, mutect2, varscan2
- FAM47B | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT tolerated (0.36); PolyPhen benign (0.112); catalogued as COSV61453604, COSV61457316; called by muse, mutect2, varscan2
- FAM83B | c.173A>T p.E58V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100174927; called by muse, mutect2, varscan2
- FASLG | c.67T>A p.W23R | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as COSV100390640; called by muse, mutect2, varscan2
- FBN2 | c.8377A>T p.S2793C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV99330218; called by muse, mutect2, varscan2
- FCRL2 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV100829993; called by muse, mutect2, varscan2
- FCRL5 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.403); catalogued as COSV100708505; called by muse, mutect2, varscan2
- FEM1A | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99521550; called by muse, mutect2, varscan2
- FGD5 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV99549092; called by muse, mutect2, varscan2
- FIGLA | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs201941812, COSV100189777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.6851C>A p.S2284Y | Missense Mutation (SNP) | VAF 63/583 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs775430967, COSV100912037; called by muse, mutect2, varscan2
- FMN2 | c.3373C>G p.P1125A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV100146943; called by muse, varscan2
- FMR1 | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV99503734; called by muse, mutect2, varscan2
- FOXB2 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.017); catalogued as rs746062219, COSV100942379; called by muse, mutect2, varscan2
- FOXB2 | c.353A>C p.H118P | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.092); catalogued as COSV100942380; called by muse, mutect2, varscan2
- FUBP1 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53928787, COSV53939327; called by muse, mutect2, varscan2
- FZD1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466437511, COSV99842713; called by muse, mutect2, varscan2
- GALC | c.689G>T p.W230L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs1410694817, COSV99730387; called by muse, mutect2, varscan2
- GBP3 | c.1466T>A p.V489E | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99352717; called by muse, mutect2, varscan2
- GGPS1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99270586; called by muse, mutect2, varscan2
- GP6 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 84/214 reads (39%) | catalogued as COSV100117730; called by muse, mutect2, varscan2
- GPIHBP1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs529580108, CM145194, COSV58209218; called by muse, varscan2
- GPR108 | c.1537G>A p.E513K (on ENST00000264080 / NM_001080452.1; = p.E271K on NM_020171.2) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99901520; called by muse, mutect2, varscan2
- GPR142 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100170720, COSV100170982; called by muse, mutect2, varscan2
- GPR174 | c.570G>C p.E190D | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99338354; called by muse, mutect2, varscan2
- GPR6 | c.96C>A p.D32E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as COSV99254513; called by muse, mutect2, varscan2
- GPR6 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99254516; called by muse, mutect2, varscan2
- GPRC6A | c.2476C>A p.L826M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs755980101, COSV59955166; called by muse, mutect2, varscan2
- GRAMD1B | c.1534G>A p.V512M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100455155; called by muse, mutect2
- GRIA2 | c.1697G>C p.R566T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99645738; called by muse, mutect2, varscan2
- GRIN2B | c.1450G>C p.G484R | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101663171; called by muse, mutect2, varscan2
- GZMH | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV99362037; called by muse, mutect2, varscan2
- HCK | c.382A>T p.I128F | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99394522; called by muse, mutect2, varscan2
- HCN1 | c.2537C>G p.S846W | Missense Mutation (SNP) | VAF 72/132 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100301983, COSV57520811; called by muse, varscan2
- HCN3 | c.1482C>G p.I494M | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100713016; called by muse, mutect2, varscan2
- HECW2 | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV53659886, COSV99648664; called by muse, mutect2, varscan2
- HELQ | c.1804A>T p.S602C | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as COSV99788073; called by muse, mutect2, varscan2
- HELZ | c.3641C>G p.T1214R | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV100699012; called by muse, mutect2
- HERC2 | c.10981G>A p.V3661I | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs368367299; called by muse, mutect2, varscan2
- HHAT | c.113A>C p.Q38P | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as COSV99805707; called by muse, mutect2, varscan2
- HK2 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV99309487; called by muse, mutect2, varscan2
- HLTF | c.396-1G>C p.X132_splice | Splice Site (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100027073; called by muse, mutect2, varscan2
- HMCN1 | c.9138A>T p.K3046N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54890205, COSV99634733; called by muse, mutect2, varscan2
- HOXD9 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99982281; called by muse, mutect2, varscan2
- HSD17B13 | c.624A>T p.K208N | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs867111910, COSV100143317; called by muse, mutect2, varscan2
- HSPG2 | c.2360del p.T787Rfs*18 | Frame Shift Del (DEL) | VAF 37/80 reads (46%) | catalogued as COSV65976916; called by pindel, varscan2
- ICE1 | c.5540G>T p.R1847I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1204388812, COSV99665556; called by muse, mutect2
- IFNA7 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT tolerated (0.6); PolyPhen benign (0.091); catalogued as COSV53330474, COSV53332060; called by muse, mutect2, varscan2
- IGDCC4 | c.2408G>T p.S803I | Missense Mutation (SNP) | VAF 82/123 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100733116; called by muse, mutect2, varscan2
- IGHV3-13 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.774); catalogued as rs557703592; called by muse, mutect2, varscan2
- IGSF9B | c.3769T>G p.S1257A | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.124); catalogued as COSV100318304; called by muse, mutect2, varscan2
- IKZF3 | c.1100C>G p.P367R | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99500116; called by muse, mutect2, varscan2
- IL1R1 | c.1422G>T p.M474I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV99292860; called by muse, mutect2, varscan2
- IL22RA2 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.149); catalogued as rs754983970, COSV99760798; called by muse, varscan2
- IMPG1 | c.2243G>T p.R748M | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100774833; called by muse, mutect2, varscan2
- IMPG1 | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs894542613, COSV100886616; called by muse, mutect2, varscan2
- IMPG1 | c.403T>A p.F135I | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV100886617; called by muse, mutect2, varscan2
- INPPL1 | c.2824G>T p.G942W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV99996594; called by muse, mutect2, varscan2
- INSRR | c.3417C>A p.D1139E | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100948013; called by muse, mutect2, varscan2
- IPO11 | c.2372A>C p.Y791S | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as COSV100321340; called by muse, mutect2, varscan2
- IQCH | c.1544C>A p.A515E | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.343); catalogued as COSV100246297; called by muse, mutect2, varscan2
- ITGA7 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as COSV57697273, COSV99151724; called by muse, mutect2
- ITGAD | c.1348G>T p.G450W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101210564; called by muse, mutect2, varscan2
- JUP | c.1441G>T p.G481C | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100159780; called by muse, mutect2, varscan2
- KATNIP | c.3021G>T p.Q1007H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV99851850; called by muse, mutect2, varscan2
- KCNA5 | c.1199G>C p.R400P | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99364147; called by muse, mutect2, varscan2
- KCNB1 | c.1685T>C p.M562T | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.505); catalogued as rs1457624910, COSV100870580; called by muse, mutect2, varscan2
- KCNB2 | c.1135A>G p.M379V | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV73049570; called by muse, mutect2, varscan2
- KCNC2 | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100129475, COSV100129709; called by muse, mutect2, varscan2
- KCNK13 | c.420G>T p.L140F | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99965895; called by muse, mutect2, varscan2
- KCNQ5 | c.1981G>A p.V661M | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as rs1360988169, COSV100572934; called by muse, mutect2, varscan2
- KDM6A | c.583G>T p.V195F | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as COSV100938535; called by muse, mutect2, varscan2
- KDM7A | c.2548G>A p.G850S | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs758963637, COSV99134567; called by muse, mutect2, varscan2
- KIAA0319 | c.2774C>A p.P925H | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100985772, COSV65500791; called by muse, mutect2, varscan2
- KIF16B | c.3084G>C p.E1028D | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV100734840; called by muse, mutect2, varscan2
- KIF1A | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100242158, COSV57485102, COSV57495072; called by muse, mutect2, varscan2
- KIF2B | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs747241718, COSV52132877, COSV99276067; called by muse, mutect2, varscan2
- KIF6 | c.905T>A p.M302K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763762810, COSV99760404; called by muse, mutect2, varscan2
- KIFAP3 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100810958, COSV63036178; called by muse, mutect2, varscan2
- KLHL34 | c.869C>A p.A290E | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV101069986; called by muse, mutect2, varscan2
- KNG1 | c.1078T>A p.W360R | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53981568; called by muse, mutect2, varscan2
- KNTC1 | c.1602C>T p.F534= | Splice Region (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100338722, COSV61083611; called by muse, mutect2
- KRT25 | c.803G>T p.R268M | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100379795; called by muse, mutect2, varscan2
- KRT6C | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99360170; called by muse, mutect2, varscan2
- LAMA3 | c.2434G>T p.A812S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV100557586; called by muse, mutect2, varscan2
- LCTL | c.1499C>A p.A500D | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.653); catalogued as COSV100328919; called by muse, mutect2, varscan2
- LIMCH1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 60/90 reads (67%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.946); catalogued as rs763838071, COSV58286155; called by muse, mutect2, varscan2
- LIN28A | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 62/97 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768587147, COSV99575458; called by muse, mutect2, varscan2
- LRFN5 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV99985230; called by muse, mutect2, varscan2
- LRGUK | c.296A>T p.E99V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99604611; called by muse, mutect2, varscan2
- LRRC6 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1321763140, COSV99138497; called by muse, mutect2, varscan2
- LRRIQ1 | c.1210G>C p.G404R | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101280691; called by muse, mutect2, varscan2
- LRRN3 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV100072976; called by muse, mutect2, varscan2
- LVRN | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV100773656; called by muse, mutect2, varscan2
- MADD | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100211901; called by muse, mutect2, varscan2
- MAGEB6 | c.261C>A p.N87K | Missense Mutation (SNP) | VAF 61/90 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100983842, COSV66871949; called by muse, mutect2, varscan2
- MAP3K1 | c.4390-2A>C p.X1464_splice | Splice Site (SNP) | VAF 23/37 reads (62%) | catalogued as COSV101267094; called by muse, mutect2, varscan2
- MAP3K8 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99552312; called by muse, mutect2, varscan2
- MAT1A | c.170-1G>C p.X57_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100944486, COSV64747046; called by muse, mutect2, varscan2
- ME1 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63841847; called by muse, mutect2, varscan2
- MED12L | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99854432; called by muse, mutect2, varscan2
- MFSD4A | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227992514, COSV100901689; called by muse, mutect2, varscan2
- MIB1 | c.2056G>T p.V686F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99839358; called by mutect2, varscan2
- MICALL2 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs762720847, COSV52519610; called by muse, varscan2
- MICALL2 | c.2515G>C p.E839Q | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV99876233; called by muse, varscan2
- MICU3 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1415869159, COSV100536533; called by muse, mutect2
- MMP17 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV100861974; called by muse, mutect2, varscan2
- MRO | c.729C>A p.Y243* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV99839504; called by muse, mutect2, varscan2
- MRPS33 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs980562741, COSV100244751; called by muse, mutect2, varscan2
- MTARC1 | c.754-2A>G p.X252_splice | Splice Site (SNP) | VAF 21/144 reads (15%) | catalogued as COSV100856351; called by muse, mutect2, varscan2
- MTMR4 | c.3131G>T p.R1044L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV60200954, COSV60202722; called by muse, mutect2, varscan2
- MTNR1B | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs146514042, CM121606, COSV57066951; called by muse, mutect2, varscan2
- MTSS1 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs985419734, COSV100275493; called by muse, mutect2, varscan2
- MYO15A | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99234228; called by muse, mutect2, varscan2
- MYO18A | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as COSV100572634; called by muse, mutect2, varscan2
- MYO9B | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763743310, COSV101261853, COSV101262002; called by muse, mutect2, varscan2
- MYOD1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as COSV100000407, COSV51455910; called by muse, mutect2
- MYT1L | c.847A>T p.R283* | Nonsense Mutation (SNP) | VAF 83/242 reads (34%) | catalogued as COSV101221334; called by muse, mutect2, varscan2
- NCAPH | c.1604A>T p.Q535L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as COSV99546151; called by muse, mutect2, varscan2
- NCOA2 | c.1731G>T p.M577I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.147); catalogued as COSV101476051; called by muse, mutect2
- NEK10 | c.2302C>G p.P768A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.711); catalogued as COSV99835622; called by muse, mutect2, varscan2
- NELL2 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100420607; called by muse, mutect2, varscan2
- NEXMIF | c.1087C>G p.Q363E | Missense Mutation (SNP) | VAF 62/98 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1569335797, COSV99281670; called by muse, mutect2, varscan2
- NFATC2 | c.1591G>A p.G531S | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs953797017, COSV101044606; called by muse, mutect2, varscan2
- NFKBIZ | c.1444-2A>C p.X482_splice | Splice Site (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100397208, COSV58201178; called by muse, mutect2, varscan2
- NISCH | c.1890G>C p.E630D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.344); catalogued as rs1257883305, COSV100617638; called by muse, mutect2, varscan2
- NLRP2 | c.505C>G p.R169G | Missense Mutation (SNP) | VAF 109/315 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV54753596, COSV99672595; called by muse, mutect2, varscan2
- NLRP8 | c.2564C>T p.T855I | Missense Mutation (SNP) | VAF 104/269 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1482464912, COSV99405859; called by muse, mutect2, varscan2
- NLRX1 | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99424821; called by muse, mutect2, varscan2
- NMNAT2 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99680339; called by muse, mutect2, varscan2
- NOS1 | c.2854G>T p.D952Y | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs759853470, COSV57605998; called by muse, mutect2, varscan2
- NR2F6 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99285822; called by muse, mutect2, varscan2
- NRAP | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 159/295 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs148205387; called by muse, mutect2, varscan2
- NRBP1 | c.1383+1G>T p.X461_splice | Splice Site (SNP) | VAF 118/284 reads (42%) | catalogued as COSV51993082, COSV99275254; called by muse, mutect2, varscan2
- NRIP2 | c.273C>G p.F91L | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100512913; called by muse, mutect2, varscan2
- NRK | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99078922, COSV99688992; called by muse, mutect2
- NT5E | c.1663C>A p.H555N | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100004321; called by muse, mutect2, varscan2
- NT5E | c.1664A>T p.H555L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100004323; called by muse, mutect2, varscan2
- NTM | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as COSV100869376, COSV66182356; called by muse, mutect2, varscan2
- OASL | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.268); catalogued as COSV99984632; called by muse, mutect2, varscan2
- OR10K2 | c.184T>A p.F62I | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59220459; called by muse, mutect2, varscan2
- OR11A1 | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101010734; called by muse, mutect2, varscan2
- OR11H12 | c.723G>T p.L241F | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.396); catalogued as rs1332924530; called by mutect2, varscan2
- OR11H6 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100209951; called by muse, mutect2, varscan2
- OR2AK2 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63549039; called by muse, mutect2, varscan2
- OR2C3 | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs147306837, COSV63574800; called by muse, mutect2, varscan2
- OR2J3 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 127/212 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV101013660; called by muse, mutect2, varscan2
- OR2M2 | c.941T>C p.L314S | Missense Mutation (SNP) | VAF 143/249 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100677309; called by muse, mutect2, varscan2
- OR2T10 | c.923A>G p.Q308R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100393795; called by muse, varscan2
- OR2T11 | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100424931; called by muse, mutect2, varscan2
- OR2T2 | c.61C>G p.H21D | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100737790; called by muse, mutect2
- OR2T4 | c.507C>A p.N169K | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV100822593; called by muse, mutect2, varscan2
- OR4C13 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV101634228; called by muse, mutect2, varscan2
- OR4C46 | c.278A>T p.N93I | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV100060942; called by muse, mutect2, varscan2
- OR4C46 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100060940, COSV60221458; called by muse, mutect2, varscan2
- OR4D2 | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV101613865, COSV73459801; called by muse, mutect2, varscan2
- OR4E2 | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100330146; called by muse, mutect2, varscan2
- OR52E8 | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV101190878; called by muse, mutect2, varscan2
- OR5AR1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100265762, COSV57255333; called by muse, mutect2, varscan2
- OR5R1 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV100393562; called by muse, varscan2
- OR5T3 | c.153G>T p.L51F | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs780288281, COSV100282917, COSV57380033; called by muse, mutect2, varscan2
- OR6C3 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV65570650; called by muse, mutect2
- OR6Q1 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1162429793, COSV100110438; called by muse, mutect2, varscan2
- OR8B4 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV100635866; called by muse, mutect2, varscan2
- OR9I1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs747198304, COSV100109879; called by muse, mutect2, varscan2
- OSBPL1A | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV100112636, COSV60203580; called by muse, mutect2, varscan2
- OSR2 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 124/219 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99882786; called by muse, mutect2, varscan2
- P2RY14 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as COSV56403421; called by muse, mutect2, varscan2
- PAPPA | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV60277604, COSV60291325; called by mutect2, varscan2
- PARP9 | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV100831249; called by muse, mutect2, varscan2
- PATZ1 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.078); catalogued as COSV99315604; called by muse, mutect2, varscan2
- PCDH11X | c.3289C>A p.R1097S | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100014580, COSV53507210; called by muse, mutect2, varscan2
- PCDHA7 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 100/168 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100971745; called by muse, mutect2, varscan2
- PDCD7 | c.1198A>G p.I400V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV99200161; called by muse, mutect2, varscan2
- PDE11A | c.846G>T p.W282C | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53710253, COSV99614504; called by muse, mutect2, varscan2
- PDE6A | c.2165C>T p.S722L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV99678632; called by muse, mutect2, varscan2
- PDE6C | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | catalogued as COSV101008844, COSV65115967; called by muse, mutect2, varscan2
- PEAK1 | c.2989C>G p.Q997E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV56931205; called by muse, mutect2, varscan2
- PEX16 | c.219G>T p.L73F | Missense Mutation (SNP) | VAF 118/369 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV99572370; called by muse, mutect2, varscan2
- PHACTR3 | c.1114C>G p.L372V | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV100733134, COSV63025030; called by muse, mutect2, varscan2
- PHC3 | c.1018C>T p.Q340* (on ENST00000494943 / NM_001308116.2; = p.Q352* on NM_024947.4) | Nonsense Mutation (SNP) | VAF 26/482 reads (5%) | catalogued as COSV101520188; called by muse, mutect2
- PHF5A | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.969); catalogued as COSV53439781, COSV99346844; called by muse, mutect2, varscan2
- PIANP | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.701); catalogued as COSV100272395, COSV57707747; called by muse, mutect2, varscan2
- PIK3CB | c.1777G>C p.A593P | Missense Mutation (SNP) | VAF 141/194 reads (73%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.555); catalogued as COSV100006020; called by muse, mutect2, varscan2
- PLEK2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs765576134, COSV99371938; called by muse, mutect2, varscan2
- PLEKHA7 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 101/186 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs755568470, COSV100850401, COSV63045716; called by muse, mutect2, varscan2
- PLOD3 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV56181558; called by muse, mutect2, varscan2
- PLSCR2 | c.574G>A p.G192S (on ENST00000497985 / NM_001199978.1; = p.G119S on NM_020359.2) | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100367663, COSV100367911; called by muse, mutect2, varscan2
- PMPCA | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100048369; called by muse, varscan2
- PMS1 | c.1315A>C p.I439L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100575770; called by muse, mutect2, varscan2
- POLDIP3 | c.359_361del p.K120del | In Frame Del (DEL) | VAF 24/168 reads (14%) | catalogued as rs773725601; called by pindel, varscan2
- POLK | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as COSV99606411; called by muse, mutect2, varscan2
- POP1 | c.244A>T p.R82* | Nonsense Mutation (SNP) | VAF 73/133 reads (55%) | catalogued as COSV100856075; called by muse, mutect2, varscan2
- PPM1L | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 81/132 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as COSV99862107; called by muse, mutect2, varscan2
- PPP3CB | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV100646259; called by muse, mutect2, varscan2
- PPP4R4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100175851; called by muse, mutect2, varscan2
- PRDM10 | c.1065G>T p.W355C | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100456998; called by muse, mutect2, varscan2
- PRKDC | c.3565G>C p.E1189Q | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV100042514; called by muse, mutect2, varscan2
- PRMT7 | c.1909-2A>T p.X637_splice | Splice Site (SNP) | VAF 17/31 reads (55%) | catalogued as COSV99546003; called by muse, mutect2, varscan2
- PROK2 | c.340G>A p.A114T (on ENST00000295619 / NM_001126128.2; = p.A93T on NM_021935.4) | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.074); catalogued as rs754857529, COSV99817061; called by muse, mutect2, varscan2
- PRPF4B | c.1324A>G p.R442G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100528361; called by muse, mutect2, varscan2
- PRPS2 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101028404; called by muse, mutect2, varscan2
- PRR5 | c.476G>T p.S159I (on ENST00000336985 / NM_181333.4; = p.S150I on NM_015366.4) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV99134838; called by muse, mutect2, varscan2
- PRRT1 | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV99278650; called by muse, mutect2, varscan2
- PSD | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV99193774; called by muse, mutect2, varscan2
- PSKH2 | c.527C>G p.A176G | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV52609305, COSV99405362; called by muse, mutect2, varscan2
- PTCH1 | c.2251-1G>T p.X751_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100109780, COSV59503652; called by muse, mutect2, varscan2
- PTCH1 | c.2251-2A>T p.X751_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100109781; called by muse, mutect2, varscan2
- PTH2R | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99782829; called by muse, mutect2, varscan2
- PTPN22 | c.1831G>A p.D611N (on ENST00000359785 / NM_001193431.2; = p.D556N on NM_012411.5) | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100703903; called by muse, mutect2, varscan2
- QTRT1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 78/113 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs371833469, COSV51550594; called by muse, mutect2, varscan2
- RAB34 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV56388726; called by muse, mutect2, varscan2
- RAD51 | c.934T>A p.C312S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99139356; called by mutect2, varscan2
- RAG2 | c.1077G>C p.Q359H | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV100271473; called by muse, mutect2, varscan2
- RAI2 | c.447T>A p.S149R | Missense Mutation (SNP) | VAF 60/90 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV100518510; called by muse, mutect2, varscan2
- RAPGEF4 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51415926, COSV99911480; called by muse, mutect2, varscan2
- RASAL1 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs1390686605, COSV55658635; called by muse, mutect2, varscan2
- RASL11A | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54080094; called by muse, mutect2, varscan2
- RBBP6 | c.1845G>C p.W615C | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100154906; called by muse, mutect2, varscan2
- RCBTB2 | c.652A>G p.M218V | Missense Mutation (SNP) | VAF 72/123 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV100749639; called by muse, mutect2, varscan2
- RIC1 | c.1522A>G p.I508V | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV52616697, COSV99317886; called by muse, mutect2, varscan2
- RICTOR | c.2192A>G p.Y731C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99705626; called by muse, mutect2
- RIF1 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99691124; called by muse, mutect2, varscan2
- RMND5B | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99200955; called by muse, mutect2, varscan2
- RNF111 | c.962C>G p.S321* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100789159; called by muse, mutect2, varscan2
- RNF128 | c.273G>T p.W91C | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100176454; called by muse, mutect2, varscan2
- RNF144A | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.953); catalogued as COSV100305870; called by muse, mutect2, varscan2
- RNF144A | c.666C>G p.F222L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV100306052, COSV57981486; called by muse, mutect2, varscan2
- RPA4 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs749282673, COSV100234912; called by muse, mutect2, varscan2
- RSRP1 | c.650C>G p.S217* | Nonsense Mutation (SNP) | VAF 34/86 reads (40%) | catalogued as COSV99682715; called by muse, mutect2, varscan2
- RTL3 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV100330048; called by muse, mutect2, varscan2
- RYR2 | c.7326G>T p.M2442I | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as COSV100772515; called by muse, mutect2, varscan2
- RYR3 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1252434951, COSV101213042; ClinVar: uncertain significance; called by muse, mutect2
- RYR3 | c.9461C>G p.P3154R (on ENST00000389232; = p.P3155R on NM_001036.6) | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV101214159; called by muse, mutect2, varscan2
- SCN11A | c.1686G>T p.Q562H | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.078); catalogued as COSV56567545; called by muse, mutect2, varscan2
- SCN3A | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV99328286; called by muse, mutect2, varscan2
- SCN8A | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 41/243 reads (17%) | catalogued as rs1555214261, COSV100634178; called by muse, mutect2, varscan2
- SDK1 | c.3915G>T p.Q1305H | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV67365923; called by muse, mutect2, varscan2
- SEC63 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100938465; called by muse, varscan2
- SELP | c.467C>G p.A156G | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99740942; called by muse, mutect2
- SEPTIN5 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100820461; called by muse, mutect2, varscan2
- SERPINA6 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0.111); catalogued as COSV100448449; called by muse, mutect2, varscan2
- SERPINB12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99501880; called by muse, mutect2, varscan2
- SESN2 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99456093; called by muse, mutect2, varscan2
- SESN2 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.414); catalogued as COSV53427520, COSV99456096; called by muse, mutect2, varscan2
- SFMBT2 | c.1862A>G p.Q621R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.992); catalogued as COSV100739560; called by muse, mutect2, varscan2
- SH3KBP1 | c.156T>A p.F52L | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV101115136; called by muse, mutect2
- SH3PXD2A | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1425147269, COSV100583797; called by muse, mutect2, varscan2
- SIGLEC10 | c.1456A>C p.N486H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100219389; called by muse, mutect2, varscan2
- SIGLEC7 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99978888; called by muse, mutect2, varscan2
- SIRPB1 | c.1084+2T>C p.X362_splice | Splice Site (SNP) | VAF 65/197 reads (33%) | catalogued as COSV99498557; called by muse, mutect2, varscan2
- SIRPB1 | c.893C>A p.A298D | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99498558; called by muse, mutect2, varscan2
- SLC10A5 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs771459899, COSV101594268; called by muse, mutect2, varscan2
- SLC12A3 | c.1981T>C p.F661L | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.05); catalogued as COSV99344657; called by muse, mutect2, varscan2
- SLC12A5 | c.568A>T p.M190L (on ENST00000454036 / NM_001134771.2; = p.M167L on NM_020708.5) | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV99716701; called by muse, mutect2, varscan2
- SLC18A2 | c.1014T>A p.S338R | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100041995; called by muse, mutect2, varscan2
- SLC19A2 | c.301_303del p.V101del | In Frame Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs767047315; called by pindel, varscan2
- SLC1A6 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 85/117 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV99694156; called by muse, mutect2, varscan2
- SLC24A3 | c.1045C>A p.R349S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV100041127, COSV100042783; called by muse, mutect2, varscan2
- SLC66A2 | c.250A>G p.M84V | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100673867; called by muse, mutect2, varscan2
- SLC7A10 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1332540111, COSV99472525; called by muse, mutect2, varscan2
- SLCO2B1 | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144448580; called by muse, mutect2, varscan2
- SLTM | c.2938G>T p.D980Y | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100998840, COSV65850161; called by muse, mutect2, varscan2
- SMAD5 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV101542580; called by muse, mutect2, varscan2
- SMG5 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as rs374912820; called by muse, mutect2, varscan2
- SMO | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs748959667, COSV50824941; called by muse, mutect2, varscan2
- SNX14 | c.1658T>C p.V553A (on ENST00000314673 / NM_001350535.1; = p.V500A on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100121738; called by muse, mutect2, varscan2
- SOAT1 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859040; called by mutect2, varscan2
- SOX30 | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV99398731; called by muse, mutect2, varscan2
- SPART | c.1669G>T p.E557* | Nonsense Mutation (SNP) | VAF 32/51 reads (63%) | catalogued as COSV62087686; called by muse, mutect2, varscan2
- SPATA17 | c.993G>T p.W331C | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100861228; called by muse, mutect2, varscan2
- SPATA31E1 | c.3604G>T p.D1202Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.697); catalogued as COSV100350973; called by muse, mutect2, varscan2
- SPATA4 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.648); catalogued as rs752920779, COSV99709090; called by muse, mutect2, varscan2
- SPHKAP | c.3326C>T p.P1109L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs756170282, COSV100764119, COSV60879220; called by muse, varscan2
- SRCAP | c.7418del p.P2473Qfs*2 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as COSV99350852; called by mutect2, varscan2
- SRGAP1 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100755068; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.838A>C p.I280L | Missense Mutation (SNP) | VAF 43/60 reads (72%) | PolyPhen possibly damaging (0.836); catalogued as COSV100085042; called by muse, mutect2, varscan2
- STEAP4 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV57328130, COSV57331236; called by muse, mutect2, varscan2
- STYXL1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV99951620; called by muse, mutect2, varscan2
- SULT1C4 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99731763; called by muse, mutect2, varscan2
- SYCP2 | c.866A>T p.D289V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100698421; called by muse, mutect2, varscan2
- SYN2 | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as COSV101426687; called by muse, mutect2, varscan2
- SYNC | c.1195G>C p.V399L | Missense Mutation (SNP) | VAF 214/305 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs1557875567, COSV100995383; called by muse, mutect2, varscan2
- SYNE1 | c.14890G>A p.E4964K (on ENST00000367255 / NM_182961.4; = p.E4893K on NM_033071.3) | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs780258342, COSV99576269; called by muse, mutect2, varscan2
- SYNE2 | c.15155A>G p.H5052R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100648389; called by muse, mutect2
- TAB3 | c.104A>T p.N35I | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99916718; called by muse, mutect2, varscan2
- TAC3 | c.68G>C p.C23S | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100269922; called by muse, mutect2, varscan2
- TAS1R2 | c.1878G>T p.K626N | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV100946346, COSV64745070; called by muse, mutect2, varscan2
- TAS1R3 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.31); PolyPhen benign (0.164); catalogued as COSV100229807; called by muse, mutect2, varscan2
- TAS2R31 | c.725T>C p.F242S | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.531); catalogued as COSV101115497; called by muse, varscan2
- TBX5 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100091992; called by muse, mutect2, varscan2
- TCHH | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV100915385; called by muse, varscan2
- TCHH | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 86/232 reads (37%) | catalogued as COSV100915386, COSV64276441; called by muse, varscan2
- TCOF1 | c.700C>G p.P234A | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0.132); catalogued as rs1400093170, COSV100078228; called by muse, mutect2, varscan2
- TENT5A | c.1076A>C p.H359P | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100199157; called by muse, mutect2, varscan2
- TFAP2B | c.1374C>G p.H458Q | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs754244526, COSV99540750; called by muse, mutect2, varscan2
- TFE3 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100252804, COSV59946599; called by muse, mutect2, varscan2
- TGFA | c.446G>C p.G149A | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV54916333, COSV99772901; called by muse, mutect2, varscan2
- TGM6 | c.1275C>A p.S425R | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99172577; called by muse, mutect2, varscan2
- THBS1 | c.1895A>G p.Q632R | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99528348; called by muse, mutect2, varscan2
- THBS4 | c.2033C>A p.P678H | Missense Mutation (SNP) | VAF 101/152 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644411, COSV63467954; called by muse, mutect2, varscan2
- THSD7B | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 95/195 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99757416; called by muse, mutect2, varscan2
- TKTL2 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as rs539836683, COSV99761701; called by muse, mutect2, varscan2
- TMEFF2 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99772292; called by muse, mutect2, varscan2
- TMEM132E | c.758T>C p.L253S (on ENST00000321639; = p.L343S on NM_001304438.2) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV100396720; called by muse, mutect2, varscan2
- TMEM134 | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100339464, COSV57281403; called by mutect2, varscan2
- TMEM150B | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100442457; called by muse, mutect2, varscan2
- TMEM242 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100900976; called by muse, mutect2, varscan2
- TMEM43 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.188); catalogued as rs1451474822, COSV55499737, COSV99853985; called by muse, mutect2, varscan2
- TMEM94 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as COSV100050851; called by muse, mutect2, varscan2
- TNFAIP3 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99397193; called by muse, mutect2, varscan2
- TRAK1 | c.2761C>A p.P921T | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100565838; called by muse, mutect2, varscan2
- TRIM32 | c.1684G>T p.G562C | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV100530070; called by muse, mutect2, varscan2
- TRPC4 | c.1679C>A p.A560E | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV100157747; called by muse, mutect2, varscan2
- TSC22D2 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV100721272; called by muse, mutect2, varscan2
- TTC39A | c.1559G>T p.R520L (on ENST00000447632 / NM_001297665.1; = p.R485L on NM_001080494.3) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV99397057; called by mutect2, varscan2
- TTN | c.100487C>T p.S33496F (on ENST00000591111; = p.S26072F on NM_003319.4) | Missense Mutation (SNP) | VAF 49/218 reads (22%) | PolyPhen probably damaging (0.998); catalogued as COSV100626922; called by muse, mutect2, varscan2
- TTN | c.68198C>A p.T22733N (on ENST00000591111; = p.T15309N on NM_003319.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | PolyPhen probably damaging (0.997); catalogued as COSV100626929; called by muse, mutect2, varscan2
- TTN | c.55463C>A p.T18488K (on ENST00000591111; = p.T11064K on NM_003319.4) | Missense Mutation (SNP) | VAF 214/469 reads (46%) | PolyPhen possibly damaging (0.676); catalogued as COSV100626933; called by muse, mutect2, varscan2
- TTN | c.19495A>G p.T6499A (on ENST00000591111; = p.T5572A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | PolyPhen benign (0); catalogued as COSV60036333; called by muse, mutect2, varscan2
- UBR1 | c.2264A>G p.Y755C | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1337625465, COSV99317755; called by muse, mutect2, varscan2
- UBXN4 | c.947G>T p.R316I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV99739550; called by muse, mutect2, varscan2
- UCP1 | c.418A>G p.R140G | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99530417; called by muse, mutect2, varscan2
- UGT2B28 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100159014; called by muse, mutect2, varscan2
- UNC13A | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99409396; called by muse, mutect2, varscan2
- UNC13A | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99409405; called by muse, mutect2, varscan2
- UNC13C | c.1580A>T p.H527L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV99522354; called by muse, mutect2, varscan2
- UNC93A | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023621, COSV57808096; called by muse, mutect2, varscan2
- USH2A | c.5718C>G p.I1906M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100241415; called by muse, mutect2, varscan2
- USH2A | c.1771G>T p.D591Y | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241419, COSV56450164; called by muse, mutect2, varscan2
- USP10 | c.1254C>G p.I418M | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs762153766, COSV99551776; called by muse, mutect2, varscan2
- UTP11 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100884984; called by muse, mutect2, varscan2
- VPS13B | c.4267C>G p.P1423A | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs754199413, COSV100663332; called by muse, mutect2, varscan2
- VWF | c.7298A>C p.H2433P | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV99779981; called by muse, mutect2, varscan2
- WFDC8 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51488582, COSV99250631; called by muse, mutect2, varscan2
- XIRP2 | c.344A>T p.D115V | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV99746695; called by muse, mutect2, varscan2
- XYLT1 | c.2384A>C p.Y795S | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99763092, COSV99763622; called by muse, mutect2, varscan2
- ZDBF2 | c.1524C>A p.Y508* | Nonsense Mutation (SNP) | VAF 21/32 reads (66%) | catalogued as COSV100985431; called by muse, mutect2, varscan2
- ZFHX4 | c.4193G>T p.R1398L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557590366, COSV51450512, COSV99254327; called by muse, mutect2, varscan2
- ZFHX4 | c.8707A>G p.S2903G | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50493593; called by muse, mutect2, varscan2
- ZFHX4 | c.10682C>A p.T3561N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99266781; called by muse, mutect2, varscan2
- ZFX | c.1405A>G p.I469V | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as COSV100458053; called by muse, mutect2, varscan2
- ZMYM2 | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV101244028; called by muse, mutect2, varscan2
- ZNF189 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs1175324470, COSV99407299; called by muse, mutect2, varscan2
- ZNF212 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as COSV100242458; called by muse, mutect2, varscan2
- ZNF274 | c.1701G>T p.E567D (on ENST00000610905; = p.E462D on NM_016324.3) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV100465432; called by muse, mutect2, varscan2
- ZNF510 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs140246987; called by muse, varscan2
- ZNF528 | c.1376A>G p.H459R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765707435, COSV100846719; called by muse, mutect2, varscan2
- ZNF544 | c.2142A>C p.K714N | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1488203277, COSV99517239; called by muse, mutect2, varscan2
- ZNF638 | c.1036A>T p.S346C | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100039748; called by muse, mutect2, varscan2
- ZNF777 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 121/195 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99925349; called by muse, mutect2, varscan2
- ZNF780B | c.1979A>G p.Q660R | Missense Mutation (SNP) | VAF 141/292 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.303); catalogued as COSV99666055; called by muse, mutect2, varscan2
- ZNF786 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 40/66 reads (61%) | catalogued as COSV100302980; called by muse, mutect2, varscan2
- ZNF804A | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100169858, COSV56441183; called by muse, mutect2, varscan2
- ZNF83 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs151319702; called by muse, mutect2, varscan2
- ZNF93 | c.164A>T p.H55L | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV100652407; called by muse, mutect2, varscan2
- ZP4 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs146820641; called by muse, mutect2, varscan2
- ZPLD1 | c.1144G>T p.G382* (on ENST00000466937 / NM_001329788.1; = p.G398* on NM_175056.2) | Nonsense Mutation (SNP) | VAF 101/264 reads (38%) | catalogued as COSV100083504, COSV60353923; called by muse, mutect2, varscan2
- ZSCAN10 | c.1146C>A p.C382* (on ENST00000252463; = p.C437* on NM_032805.3) | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV52969316, COSV99374295; called by muse, mutect2, varscan2
- ACACA | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CCL23 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- COL6A3 | c.4752del p.T1585Pfs*21 | Frame Shift Del (DEL) | VAF 16/158 reads (10%) | called by mutect2, pindel*
- CYTIP | c.182del p.L61* | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- DLG2 | c.457del p.V153* | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- EIF4A2 | c.1134_1138del p.E379Rfs*7 | Frame Shift Del (DEL) | VAF 33/251 reads (13%) | called by mutect2, pindel, varscan2
- GIPR | c.793+1dup | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- HEATR9 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV4-28 | c.185G>C p.G62A | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IGKV3D-11 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MEX3C | c.1871G>C p.G624A | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYL6 | c.427+3_427+9del p.X143_splice | Splice Site (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- NOXA1 | c.242_260del p.A81Gfs*16 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by pindel, varscan2
- OR4X1 | c.367del p.A123Pfs*12 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by mutect2, varscan2
- PRAMEF15 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SDE2 | c.1267del p.A423Qfs*24 | Frame Shift Del (DEL) | VAF 55/108 reads (51%) | called by mutect2, pindel, varscan2
- SHARPIN | c.244_245del p.G83Pfs*76 | Frame Shift Del (DEL) | VAF 47/85 reads (55%) | called by mutect2, pindel, varscan2
- TPTE | c.919C>A p.H307N (on ENST00000618007 / NM_199261.4; = p.H289N on NM_199259.4) | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRAV5 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIAP | c.607_609del p.C203del | In Frame Del (DEL) | VAF 16/50 reads (32%) | called by pindel, varscan2
- ABCC8 | c.1599C>A p.L533= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as COSV100217651, COSV56858728; called by muse, varscan2
- AC008676.3 | c.459G>A p.E153= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100400493; called by muse, mutect2
- AC092143.1 | c.2037C>T p.A679= | Silent (SNP) | VAF 46/186 reads (25%) | catalogued as COSV100206046; called by muse, mutect2, varscan2
- ACOX1 | c.1395A>G p.P465= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as rs960281087, COSV99503935; called by muse, mutect2, varscan2
- ACSM4 | c.516C>A p.A172= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV101257323; called by muse, mutect2, varscan2
- ADAMTS18 | c.2112A>T p.G704= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as COSV99273933; called by muse, mutect2, varscan2
- ADGRV1 | c.16998C>T p.A5666= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as COSV101316403; called by muse, mutect2, varscan2
- BABAM2 | c.645G>T p.V215= | Silent (SNP) | VAF 58/140 reads (41%) | catalogued as COSV100568700; called by muse, varscan2
- BAZ1B | c.2190A>G p.E730= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100290067; called by muse, mutect2, varscan2
- CCL23 | c.126A>G p.V42= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1311388628; called by muse, mutect2, varscan2
- CDC42EP4 | c.531C>T p.P177= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as rs778993386, COSV100231971; called by muse, mutect2, varscan2
- CDH18 | c.651T>A p.I217= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99937799; called by muse, mutect2, varscan2
- CFAP44 | c.2058A>G p.L686= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV99870252; called by muse, mutect2, varscan2
- CFAP54 | c.6705A>C p.P2235= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV100733300; called by muse, mutect2, varscan2
- CHAT | c.1107G>C p.V369= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100340781, COSV60331064; called by muse, mutect2, varscan2
- CLCA2 | c.1953T>C p.P651= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as COSV100991690; called by muse, mutect2, varscan2
- CRYBB1 | c.189C>T p.V63= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV53235094, COSV99315885; called by muse, mutect2, varscan2
- CTNND2 | c.2559G>T p.L853= | Silent (SNP) | VAF 52/164 reads (32%) | catalogued as COSV100480489; called by muse, mutect2, varscan2
- DGKI | c.2409C>A p.S803= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99936942; called by muse, mutect2, varscan2
- DNAAF5 | c.882C>G p.L294= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV99860252; called by muse, mutect2, varscan2
- DNMBP | c.6G>A p.E2= | Silent (SNP) | VAF 51/116 reads (44%) | catalogued as COSV100144349; called by muse, mutect2, varscan2
- DPEP2 | c.672C>T p.S224= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs781016620; called by muse, varscan2
- DST | c.16377T>A p.I5459= (on ENST00000361203 / NM_001374722.1; = p.I3047= on NM_015548.5) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99759337; called by muse, mutect2
- ENPP7 | c.42G>T p.T14= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100093659; called by muse, mutect2, varscan2
- EPPK1 | c.3963G>A p.E1321= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV101599943, COSV73262257; called by muse, mutect2, varscan2
- FAM47A | c.753T>A p.P251= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as COSV100650038; called by muse, mutect2, varscan2
- FCAMR | c.165A>G p.L55= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100249715; called by muse, mutect2
- FGF4 | c.543G>C p.L181= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99395474; called by muse, mutect2, varscan2
- FLRT2 | c.1686T>C p.F562= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV100420923; called by muse, mutect2, varscan2
- GABRP | c.651C>A p.T217= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as COSV99517060; called by muse, mutect2, varscan2
- GALK1 | c.600C>T p.L200= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99849633; called by muse, mutect2, varscan2
- GPI | c.1308G>A p.L436= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100731565; called by muse, mutect2, varscan2
- GPRC6A | c.2475C>A p.I825= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV59952644, COSV59955932; called by muse, mutect2, varscan2
- HCN1 | c.2541G>T p.S847= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as COSV57502512; called by muse, varscan2
- HECW2 | c.2157G>T p.G719= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV53664303; called by muse, mutect2, varscan2
- HESX1 | c.309G>A p.L103= | Silent (SNP) | VAF 72/428 reads (17%) | called by muse, varscan2
- HFM1 | c.3795A>G p.E1265= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV54031411; called by muse, mutect2, varscan2
- HJV | c.345C>A p.I115= (on ENST00000336751 / NM_213653.4; = p.I2= on NM_145277.5) | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs142575526, COSV60951213; called by muse, mutect2, varscan2
- IGF2R | c.6609C>T p.F2203= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100808063; called by muse, mutect2, varscan2
- IGHG3 | c.231C>A p.G77= | Silent (SNP) | VAF 69/120 reads (58%) | called by muse, mutect2, varscan2
- IL24 | c.258C>A p.I86= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV99686549; called by muse, mutect2, varscan2
- KIF16B | c.2052G>T p.L684= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as COSV100734841; called by muse, mutect2, varscan2
- KIR3DL2 | c.258C>A p.T86= | Silent (SNP) | VAF 86/187 reads (46%) | catalogued as COSV99552306; called by muse, mutect2, varscan2
- KLRC4 | c.261G>A p.V87= | Silent (SNP) | VAF 63/205 reads (31%) | catalogued as COSV100511348; called by muse, mutect2, varscan2
- LAMB4 | c.2943A>G p.P981= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV99225391; called by muse, mutect2, varscan2
- LCE2D | c.294G>A p.G98= | Silent (SNP) | VAF 28/204 reads (14%) | catalogued as rs566463390, COSV100909572; called by muse, varscan2
- LRP1B | c.1572C>T p.F524= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV101260079, COSV67202843; called by muse, mutect2, varscan2
- LRP1B | c.921C>A p.I307= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV101258011, COSV101260081; called by muse, mutect2, varscan2
- LSG1 | c.321C>T p.N107= | Silent (SNP) | VAF 25/393 reads (6%) | catalogued as COSV99503505; called by muse, mutect2
- LUC7L | c.831G>T p.R277= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99551430; called by muse, mutect2, varscan2
- MEP1B | c.279T>C p.N93= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99329100; called by muse, mutect2
- MGLL | c.219C>T p.F73= (on ENST00000398104 / NM_001003794.2; = p.F83= on NM_007283.6) | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as rs775022435, COSV54029531, COSV99412295; called by muse, mutect2, varscan2
- MMP16 | c.786C>A p.A262= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV99690098; called by muse, mutect2, varscan2
- MSLN | c.996G>T p.L332= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99558667; called by muse, mutect2, varscan2
- MSLNL | c.1194G>T p.T398= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99558670; called by muse, mutect2, varscan2
- MUC17 | c.2652C>T p.T884= | Silent (SNP) | VAF 114/481 reads (24%) | catalogued as rs138339911, COSV100074828; called by muse, mutect2, varscan2
- NCF4 | c.939C>G p.L313= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99957514; called by muse, mutect2, varscan2
- NETO2 | c.444A>G p.E148= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100292584; called by muse, mutect2, varscan2
- NEURL1 | c.93C>A p.I31= | Silent (SNP) | VAF 37/230 reads (16%) | catalogued as COSV100872823, COSV63915584; called by muse, mutect2, varscan2
- NIN | c.5235G>A p.Q1745= (on ENST00000382041 / NM_182946.1; = p.Q1032= on NM_016350.4) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs748459650, COSV99815022; called by muse, mutect2, varscan2
- NLRP2 | c.663G>T p.T221= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV99672596; called by muse, mutect2, varscan2
- NLRP3 | c.2631C>A p.A877= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1401066630, COSV100276552; called by muse, mutect2, varscan2
- NRROS | c.1935G>T p.R645= | Silent (SNP) | VAF 466/559 reads (83%) | catalogued as COSV60746875; called by muse, mutect2, varscan2
- NT5C1B | c.834C>T p.Y278= (on ENST00000359846 / NM_001199086.2; = p.Y218= on NM_033253.4) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV58395730; called by muse, mutect2, varscan2
- NUGGC | c.2100G>A p.E700= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs770091256, COSV100429589; called by muse, varscan2
- OR2M2 | c.558C>A p.I186= | Silent (SNP) | VAF 45/317 reads (14%) | catalogued as rs955591750, COSV100677308; called by muse, mutect2, varscan2
- OR2M5 | c.459T>C p.S153= | Silent (SNP) | VAF 65/323 reads (20%) | catalogued as rs553316282, COSV100822859, COSV100822867; called by muse, mutect2, varscan2
- OR4C16 | c.858G>C p.T286= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV100114231, COSV58942344, COSV58943104; called by muse, mutect2, varscan2
- OR4K14 | c.294T>C p.C98= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100520516; called by muse, mutect2, varscan2
- OR4Q3 | c.582C>T p.I194= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV100057331, COSV59177139; called by muse, mutect2, varscan2
- OR52E6 | c.723C>A p.T241= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs371025632; called by muse, mutect2, varscan2
- OR5AU1 | c.141C>A p.L47= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV100436119; called by muse, mutect2, varscan2
- OR5D18 | c.441G>T p.V147= | Silent (SNP) | VAF 54/158 reads (34%) | catalogued as COSV100450855, COSV61736924; called by muse, varscan2
- OR5D18 | c.705C>A p.R235= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100450856; called by muse, mutect2, varscan2
- OR9Q1 | c.291T>C p.C97= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV100110439; called by muse, mutect2, varscan2
- ORC2 | c.366A>G p.S122= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1489233639, COSV99309710; called by muse, mutect2, varscan2
- PCDH11X | c.561C>A p.L187= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as COSV100014575, COSV53509124; called by muse, mutect2, varscan2
- PCDHA7 | c.2049G>T p.S683= | Silent (SNP) | VAF 57/81 reads (70%) | catalogued as COSV100970984, COSV65336822; called by muse, mutect2, varscan2
- PCDHGA9 | c.480G>T p.P160= | Silent (SNP) | VAF 49/76 reads (64%) | catalogued as COSV99545625, COSV99549718; called by muse, mutect2, varscan2
- PCNT | c.633C>T p.F211= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100855981; called by muse, mutect2, varscan2
- PHF21A | c.1282A>C p.R428= (on ENST00000418153 / NM_001101802.3; = p.R429= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as COSV99139217; called by muse, mutect2, varscan2
- PKHD1L1 | c.9567G>A p.V3189= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs945934182, COSV101006738; called by muse, mutect2, varscan2
- PRAMEF15 | c.186C>G p.P62= | Silent (SNP) | VAF 37/89 reads (42%) | called by muse, varscan2
- PRKD3 | c.2328T>C p.F776= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV99306664; called by muse, mutect2, varscan2
- PRLHR | c.909C>T p.L303= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV53305538; called by muse, mutect2, varscan2
- PRRG1 | c.159T>C p.N53= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV101069107; called by muse, mutect2, varscan2
- PRX | c.1908C>G p.L636= | Silent (SNP) | VAF 31/276 reads (11%) | catalogued as COSV99398009; called by muse, mutect2, varscan2
- PTPN21 | c.2181G>T p.A727= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as rs756344360, COSV100162463; called by muse, mutect2
- RAB3IP | c.801T>C p.P267= (on ENST00000550536 / NM_175623.4; = p.P251= on NM_022456.5) | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV99923562; called by muse, mutect2, varscan2
- RAF1 | c.1200A>T p.T400= | Silent (SNP) | VAF 41/65 reads (63%) | catalogued as COSV99313300; called by muse, mutect2, varscan2
- RCC1 | c.525A>G p.V175= | Silent (SNP) | VAF 41/61 reads (67%) | catalogued as COSV100868186; called by muse, mutect2, varscan2
- RGS22 | c.246T>C p.Y82= | Silent (SNP) | VAF 49/97 reads (51%) | catalogued as rs1379202014, COSV100693707; called by muse, mutect2, varscan2
- RGS4 | c.198G>A p.L66= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100905604; called by muse, mutect2, varscan2
- RPL10L | c.321G>A p.G107= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100022735; called by muse, mutect2, varscan2
- RYR2 | c.6495G>T p.L2165= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100772514; called by muse, mutect2, varscan2
- S1PR1 | c.891G>T p.L297= | Silent (SNP) | VAF 122/198 reads (62%) | catalogued as rs1416190503, COSV100541636; called by muse, mutect2, varscan2
- SCN4A | c.3015C>A p.L1005= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV101438631; called by muse, mutect2, varscan2
- SCN5A | c.4443G>T p.G1481= (on ENST00000333535 / NM_198056.3; = p.G1480= on NM_000335.5) | Silent (SNP) | VAF 58/87 reads (67%) | catalogued as COSV100350252; called by muse, mutect2, varscan2
- SF3B1 | c.1612C>T p.L538= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs377652778; called by muse, mutect2, varscan2
- SGO2 | c.2088C>A p.T696= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100764785; called by muse, mutect2, varscan2
- SLC12A7 | c.2232G>T p.R744= | Silent (SNP) | VAF 36/158 reads (23%) | catalogued as COSV99370475; called by muse, mutect2, varscan2
- SLC16A14 | c.396C>T p.V132= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs753163018, COSV54617236; called by muse, mutect2, varscan2
- SLC17A6 | c.1257A>G p.A419= | Silent (SNP) | VAF 34/313 reads (11%) | catalogued as rs201311311, COSV54136411; called by muse, mutect2, varscan2
- SLC35F4 | c.636C>A p.V212= (on ENST00000339762 / NM_001352015.2; = p.V176= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100334167; called by muse, mutect2, varscan2
- SLC7A6OS | c.513G>A p.L171= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs1247907996, COSV99546806; called by muse, mutect2, varscan2
- SPHKAP | c.3360G>T p.S1120= | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as COSV100764506, COSV60878017, COSV60894188; called by muse, varscan2
- SPIB | c.204T>C p.F68= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV99570125; called by muse, mutect2, varscan2
- SPINT1 | c.204G>C p.S68= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100689195; called by muse, varscan2
- SPTA1 | c.3120G>T p.P1040= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as rs200809766; called by muse, mutect2, varscan2
- SPTA1 | c.1185T>C p.A395= | Silent (SNP) | VAF 76/260 reads (29%) | catalogued as rs1180964048, COSV100935469, COSV63752385; called by muse, mutect2, varscan2
- SUPT5H | c.1767A>G p.S589= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV100782140; called by muse, mutect2, varscan2
- SYNJ2 | c.1893C>T p.G631= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100840624; called by muse, mutect2, varscan2
- TAS2R60 | c.714T>C p.S238= | Silent (SNP) | VAF 60/110 reads (55%) | catalogued as rs1226218362, COSV100223658; called by muse, mutect2, varscan2
- TBC1D4 | c.2214A>G p.S738= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100884769; called by muse, mutect2, varscan2
- TEX15 | c.3063A>C p.V1021= (on ENST00000256246; = p.V1404= on NM_001350162.2) | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV99822003; called by muse, mutect2, varscan2
- TMEM74 | c.495A>G p.S165= | Silent (SNP) | VAF 52/100 reads (52%) | catalogued as COSV99865866; called by muse, mutect2, varscan2
- TMTC3 | c.2370T>C p.A790= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV99898640; called by muse, mutect2, varscan2
- TTN | c.69783C>A p.A23261= (on ENST00000591111; = p.A15837= on NM_003319.4) | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV100626925; called by muse, mutect2, varscan2
- UNC13D | c.846C>T p.L282= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99257373; called by muse, mutect2, varscan2
- USF3 | c.2793A>G p.L931= | Silent (SNP) | VAF 50/179 reads (28%) | catalogued as COSV100325720; called by muse, mutect2, varscan2
- USH2A | c.2499C>T p.N833= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV100241417, COSV56430261; called by muse, mutect2, varscan2
- VIRMA | c.3999G>T p.T1333= | Silent (SNP) | VAF 49/106 reads (46%) | catalogued as COSV99889305; called by muse, mutect2, varscan2
- VWF | c.5226C>T p.D1742= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs748715084, COSV54618295; called by muse, mutect2, varscan2
- XIRP2 | c.8265G>C p.V2755= (on ENST00000628543; = p.V2930= on NM_152381.6) | Silent (SNP) | VAF 54/91 reads (59%) | catalogued as COSV99746698; called by muse, mutect2, varscan2
- ZBTB22 | c.57G>T p.L19= | Silent (SNP) | VAF 61/98 reads (62%) | catalogued as COSV99802581; called by muse, mutect2, varscan2
- ZDHHC19 | c.543C>T p.R181= | Silent (SNP) | VAF 215/267 reads (81%) | catalogued as rs370959927, COSV56348176; called by muse, mutect2, varscan2
- ZIC4 | c.918C>T p.L306= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs750237984, COSV101268127, COSV67171510; called by muse, mutect2, varscan2
- ZNF473 | c.915A>G p.T305= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV99569058; called by muse, mutect2, varscan2
- ZNF521 | c.2140C>T p.L714= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100833222; called by muse, mutect2, varscan2
- ZNF8 | c.438G>A p.Q146= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99544162, COSV99544522; called by muse, mutect2, varscan2
- ZNF98 | c.24A>G p.L8= | Silent (SNP) | VAF 54/286 reads (19%) | catalogued as COSV100757595; called by muse, mutect2, varscan2
- AC244258.1 | n.558A>G | RNA (SNP) | VAF 16/32 reads (50%) | catalogued as rs768640354; called by muse, mutect2, varscan2
- CALCA | chr11:14967698 G>A | 3'Flank (SNP) | VAF 27/164 reads (16%) | catalogued as rs781931981, COSV100524099; called by muse, mutect2, varscan2
- GRHL3 | c.1694+4313C>G | Intron (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99134383; called by muse, mutect2, varscan2
- IDH3B | c.*305C>T | 3'UTR (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100250311; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331448 del C | 5'Flank (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- MTUS2 | c.-7G>C | 5'UTR (SNP) | VAF 24/49 reads (49%) | catalogued as COSV70916074; called by muse, mutect2, varscan2
- NACA | c.70+3818del | Intron (DEL) | VAF 23/73 reads (32%) | catalogued as rs754174182; called by mutect2, pindel, varscan2
- NDUFA13 | chr19:19516187 G>T | 5'Flank (SNP) | VAF 25/95 reads (26%) | catalogued as COSV99389233; called by muse, mutect2, varscan2
- NID2 | c.-2G>C | 5'UTR (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99357153; called by muse, mutect2, varscan2
- OR3A4P | n.838C>A | RNA (SNP) | VAF 120/197 reads (61%) | called by muse, mutect2, varscan2
- PDILT | c.-1C>T | 5'UTR (SNP) | VAF 12/80 reads (15%) | catalogued as COSV100199778; called by muse, mutect2
- SNORD115-16 | n.80C>A | RNA (SNP) | VAF 149/379 reads (39%) | called by muse, mutect2, varscan2
- SUGP1 | c.539-80C>A | Intron (SNP) | VAF 95/315 reads (30%) | catalogued as COSV99895190, COSV99895505; called by muse, mutect2, varscan2
- TTN | c.10360+4363G>C | Intron (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100626940; called by muse, varscan2
- ZNF99 | c.*609C>A | 3'UTR (SNP) | VAF 36/138 reads (26%) | catalogued as COSV101233937; called by muse, varscan2
- ZNF99 | c.4-607A>C | Intron (SNP) | VAF 15/77 reads (19%) | catalogued as COSV101233938; called by muse, mutect2, varscan2
